TCGA case TCGA-IK-7675 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a5f851c5-6130-4ea1-9f86-be59331a92f7

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 43 years; Vital status: Dead; Days to death: 578 days (1.6 years).

Diagnoses (2)
1. Oligodendroglioma, NOS (the primary disease): ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 43.5 years (15,900 days); Year of diagnosis: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Motor or Movement Changes; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 46 days; Days to treatment end: 88 days; Treatment dose: 5,400 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Days to treatment start: 531 days (1.5 years); Days to treatment end: 552 days (1.5 years).
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Days to treatment end: 510 days (1.4 years).
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 43.9 years (16,023 days); Days to diagnosis: 123 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 48 days; Karnofsky performance status: 90.
- Day 123 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 578 days (1.6 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Motor / Movement Change.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IK-7675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-IK-7675-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-IK-7675-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-IK-7675-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IK-7675-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: Yes; Related symptom first present: Motor/Movement Changes; First symptom longest duration: 0 - 30 Days; History asthma: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes; Family history brain tumor: No.
- Follow-up form: Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 578 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 578 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 123 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IK-7675-01A-11D-2085-01): tumor purity 1, ploidy 1.89, whole-genome doublings 0.
